Gene-level copy-number profile of tumor specimen TARGET-51-PALFEF-01A from TARGET case TARGET-51-PALFEF, project TARGET-CCSK (Clear Cell Sarcoma of the Kidney). Sex at birth: male; Vital status: Alive; Primary diagnosis: Clear cell sarcoma of kidney; Tissue or organ of origin: Kidney, NOS; Age at diagnosis: 1.6 years (595 days).
Specimen TARGET-51-PALFEF-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TARGET-CCSK.5935c02f-6540-5eef-91ca-cce876f913a6.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TARGET-51-PALFEF-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 349 have no estimate.
https://portal.gdc.cancer.gov/files/c9a9452d-6054-46bd-8098-65169d5749a0

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 2,389; copy number 1: 458; copy number 2: 57,391; copy number 3: 20; copy number 4: 1; copy number 5: 3; copy number 6: 12.

Homozygous deletions (total copy number 0; autosomes only): 10 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:127,170,011–127,170,231, 1 gene: NIFKP9.
- chr13:38,922,727–38,936,199, 1 gene: ANKRD26P2.
- chr13:57,204,379–57,204,799, 1 gene: MTCO2P3.
- chr22:25,351,418–25,520,854, 7 genes (within-gene range 0–2): LRP5L, AL022324.3, AL008721.1, IGLVIVOR22-1, CRYBB2P1, MIR6817, AL008721.2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 15 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr10:133,520,406–133,561,220, 1 gene, copy number 6 (within-gene range 2–6): CYP2E1.
- chr10:133,541,809–133,642,894, 8 genes, copy number 6: AL161645.2, SYCE1, AL731769.2, OR6L1P, AL731769.1, FRG2B, RARRES2P2, AGGF1P2.
- chr12:31,111,652–31,252,597, 3 genes, copy number 6 (within-gene range 2–6): AC024940.1, AC024940.4, AC024940.2.
- chr18:29,048,620–29,361,963, 3 genes, copy number 5: RNU6-408P, AC105245.1, AC074237.1.

Autosomal genes at a single copy (total copy number 1): 449. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
